Gene-level copy-number profile of tumor specimen TCGA-06-0130-01A from TCGA case TCGA-06-0130, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.2 years (19,812 days).
Specimen TCGA-06-0130-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.d9fc7b42-ce16-431d-9f68-3abb664e618d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0130-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e55a854-69c8-4407-9786-5b02abce4c74

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 17,481; copy number 2: 38,497; copy number 3: 3,080; copy number 4: 748.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0130-01A-01D-0214-01): tumor purity 0.27, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:80,527,960–81,431,520, 6 genes: RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1.
- chr14:89,124,871–89,619,149, 1 gene (within-gene range 0–1): FOXN3.
- chr14:89,290,205–89,409,469, 4 genes: CAP2P1, AL357093.2, AL357093.1, AL356805.1.
- chr14:89,417,354–89,419,793, 1 gene: FOXN3-AS1.
- chr14:92,513,781–92,748,679, 2 genes: RIN3, LGMN.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 15,100. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
